Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IN, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IN-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT (

Patient Name:

Med. Rec. #:

DOB: (Age:

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type: INPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Bladder carcinoma. HG T2 lesion

invaded prostate and obstructing left UO.

Specimens Submitted:

- 1: Prostate (fs)
- 2: Anterior rectal mass (fs)
- 3: Right pelvic lymph nodes
- 4: Left pelvic lymph nodes
- 5: Bladder, urethra, urachus, prostate, seminal vesicles, peri-vesicle tissue and lymph nodes; cystoprostatectomy
- 6: Right pelvic lymph nodes
- 7: Left vas deferens
- 8: Urethral margin
- 9: Left distal ureter
- 10: Right periureteral tissue
- 11: Right distal ureter large clip on proximal margin

DIAGNOSIS:

1. Prostate; biopsy:
-Invasive urothelial carcinoma involving fibrous tissue.
2. Anterior rectal mass; biopsy:
-Prostatic tissue with acute and chronic inflammation and marked cautery artifact.
-No carcinoma seen.

3. **Right pelvic lymph nodes:**
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 5

ICD-0-3
carcinoma, urothelial, NOS 8120/3
Path site: bladder, NOS C67.9
CQCF: bladder, wall, lateral C67.2 *fw*
12/7/11

4. **Left pelvic lymph nodes:**
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 7

5. **Bladder, urethra, urachus, prostate, seminal vesicles, peri-vesicle tissue and lymph nodes; cystoprostatectomy:**
a.

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Perivesical soft tissues

Extravesical Tumor Extension:

Right ureter involved

Left ureter involved

Urethra uninvolved

Periurethral prostatic ducts involved

Prostatic stroma involved

The left seminal vesicle wall and the fibroadipose tissue surrounding the right seminal vesicle are involved.

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Tumor present at perivesical soft tissue margin anteriorly _____

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting ulceration

Prostate:

Other Prostatic stroma involved

Seminal Vesicles:

Other Left seminal vesicle involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT3 (Invasion of perivesicle soft tissue)

PR2 (Periprostic or periseminal vesicle soft tissue invasion) tissue invasion)

Comment: According to 7th edition of the AJCC Cancer Staging Manual, this tumor would be staged as T4a.

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

Tumor Location:

Involves Right anterior

Dominant tumor mass located in: right anterior mid

Vascular Invasion:

Not Identified

Perineural Invasion:

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

Not identified

Tumor Multicentricity:
Not identified

High Grade Prostatic Intraepithelial Neoplasia:
Identified

Capsule:
Tumor confined to prostate

Seminal Vesicles:
Not involved

Bladder Neck:
Not Involved

Surgical Margins:
Free of tumor

Non-Neoplastic Prostate:
Exhibits nodular hyperplasia

Staging (AJCC 1997):
pT2a (confined to the prostate & capsule, involving one lobe)

6. Right pelvic lymph nodes:

Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 2

7. Vas deferens, left;excision:
- Benign vasculature and fibroadipose tissue.
8. Urethral margin;excision:
- Benign urethra.
9. Ureter, left distal;excision:
- Benign ureter with acute inflammation and reactive atypia.
10. Right periureteral tissue;excision:
- Benign fibroadipose tissue.
11. Ureter, right distal; excision:
- Benign ureter.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

[page 4 of 7]
SURGICAL PATHOLOGY REPORT

1. The specimen is received fresh, labeled "prostate", and consists of a piece of tan soft tissue measuring 2.5 x 1.7 x 0.4 cm. The specimen is entirely submitted for frozen section diagnosis.

Summary of sections:

FSC - frozen section control

2. The specimen is received fresh, labeled "anterior rectal mass", and consists of multiple pieces of tan soft tissue ranging from 0.3 to 1.5 cm in greatest dimension. The larger piece is bisected, and the specimen is entirely submitted for frozen section diagnosis.

Summary of sections:

FSC - frozen section control

3. The specimen is received in formalin, labeled "right pelvic lymph node", and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.2 cm to 2.4 cm in greatest dimension. Cut section reveals that the largest lymph node is grossly positive. All additional identified lymph nodes are entirely submitted.

Summary of sections:

GPLN - grossly positive lymph node

LN-lymph nodes

BLN-bisected lymph nodes

4. The specimen is received in formalin labeled "left pelvic lymph node", and consists of multiple pink tan fatty lymph nodes with attached fatty fibrous tissue ranging from 0.4 cm to 4.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph nodes

LN1 - half of largest lymph node

ADD - remaining half of largest lymph node

5. The specimen is received fresh, labeled "bladder, prostate, urethra, urachus, seminal vesicles and perivesical tissue and lymph nodes". It consists of a bladder with attached prostate and seminal vesicles measuring 17.0 cm from superior to inferior, 11.5 cm from medial to lateral, and 7.2 cm from anterior to posterior. The bladder measures 7.5 x 6.5 x 3.5 cm and the prostate measures 4.6 x 4.2 x 4.0 cm. The right half of the bladder and prostate is inked green; the left half of the bladder and prostate is inked blue. The prostatic urethral margin is shaved and submitted en face. The bladder is opened along the anterior midline to reveal a tan-yellow friable papillary centrally necrotic tumor involving predominately the left posterior and left lateral wall extending down the trigone measuring 6.1 x 4.5 x 1.8 cm. The friable tissue partially occludes the left ureteral orifice and grossly approaches the right ureteral orifice. The tumor extends into the prostatic parenchyma and lies 3.6 cm from the prostatic urethral margin. The tumor is sectioned to reveal gross extension through the bladder wall into the perivesical fat. A full face section is taken, bisected, and submitted accordingly. The tumor also approaches the anterior soft tissue margin, and grossly invades the seminal vesicles bilaterally. There is an additional ulcerated lesion in the dome of bladder that measures 2.2 x 1.8 cm and lies 1.8 cm from the trigone, 2.5 cm from the right ureteral orifice, and 3.2 cm from the left ureteral orifice. The remaining bladder mucosa is dusky and congested. TPS from both ulcerated tumor foci are submitted. Representative sections are submitted for routine processing.

Summary of sections:

UTHM - urethral margin

RUM - right ureter margin

LUM - left ureter margin

TAM - tumor to anterior soft tissue margin

TP - tumor to posterior soft tissue margin

TPR - tumor to prostate

TU - tumor to prostatic urethra

TF - tumor to fat (full face section)

TU - tumor to urethra

UD - ulcerated defect within the dome

RUO - right ureter orifice

LUO - left ureter orifice to left ureter (bisected)

LU - remaining left ureter

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

LP - left posterior wall
LA - left anterior wall
RP - right posterior wall
RA - right anterior wall
TRI - trigone
DOM - dome
PU - prostatic urethra
RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate

6. The specimen is received fresh, labeled "right pelvic lymph nodes", and consists of one pink tan firm lymph node, which measures 3.5 x 0.4 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

BLN - lymph node

7. The specimen is received in formalin labeled, "left vas deferens", and consists of a 3.5 x 2.5 x 0.7 cm portion of yellow-tan, lobulated fibroadipose tissue with two attached, tan-brown, patent luminal structures. Sectioning reveals rubbery cut surfaces with no gross lesions. Representative sections are submitted.

Summary of sections:

U -- undesignated

8. The specimen is received in formalin, labeled "urethral margin", and consists of a single irregular portion of brown-tan, focally hemorrhagic soft tissue measuring 1.5 x 0.9 x 0.6 cm. The specimen is entirely submitted.

Summary of sections:

U -- undesignated

9. The specimen is received in formalin, labeled "left distal ureter", and consists of a segment of ureter measuring 1.3 x 0.5 x 0.4 cm. The specimen is entirely submitted.

Summary of sections:

U -- undesignated

10. The specimen is received in formalin, labeled, "right periureteral tissue" and consists of a segment of ureter measuring 1.7 x 1.3 x 0.8 cm. The specimen is entirely submitted.

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

Summary of sections:
U -- undesignated

11. The specimen is received in formalin labeled, "right distal ureter, large clip on proximal margin", and consists of a segment of ureter measuring 1.4 x 1 cm with a clip at one end. The clipped end has been designated the margin by the surgeon and is inked blue. Sectioning reveals a pinpoint lumen. The specimen is entirely submitted.

Summary of sections:
CE - clipped end
SS - serial sections

Summary of Sections:

Part 1: Prostate (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Anterior rectal mass (fs)

Block	Sect. Site	PCs
1	FSC	5

Part 3: Right pelvic lymph nodes

Block	Sect. Site	PCs
2	ADD	2
3	BLN	3
1	GPLN	1
1	LN	1

Part 4: Left pelvic lymph nodes

Block	Sect. Site	PCs
2	LN	2
4	LN1	4

Part 5: Bladder, urethra, urachus, prostate, seminal vesicles, peri-vesicle tissue and lymph nodes; cystoprostatectomy

Block	Sect. Site	PCs
6	ADD	7
1	DOM	1
1	LA	1
1	LAB	1
1	LAM	1
1	LAP	1
1	LP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LU	1
1	LUM	1
2	LUO	2
1	PU	1
1	RA	1
1	RAB	1
1	RAM	1

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

1	RAP	1
1	RP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
2	TAM	2
2	TF	2
2	TP	2
2	TPR	2
1	TRI	1
2	TU	2
2	UD	2
1	UTHM	1
1	VD	1

Part 6: Right pelvic lymph nodes

Block	Sect. Site	PCs
2	BLN	2

Part 7: Left vas deferens

Block	Sect. Site	PCs
1	U	3

Part 8: Urethral margin

Block	Sect. Site	PCs
1	U	1

Part 9: Left distal ureter

Block	Sect. Site	PCs
1	U	1

Part 10: Right periureteral tissue

Block	Sect. Site	PCs
1	U	1

Part 11: Right distal ureter large clip on proximal margin

Block	Sect. Site	PCs
1	CE	1
1	SS	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Prostate (fs): Poorly differentiated carcinoma with similar morphologic features to the prior bladder tumor

Permanent Diagnosis: Same

2. Frozen Section Diagnosis: Anterior rectal mass (fs): Prostatic tissue with a focus showing marked cautery artifact, cannot further classify on frozen

Permanent Diagnosis: See final diagnosis.

Source: NCI Genomic Data Commons file d297e1dd-caf8-4910-9ca0-6b8d7187caa4 (TCGA-DK-A3IN.750A04D5-2521-4E30-AEE6-E79BA25D6CC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).